Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A51D, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A51D-01A (Primary Tumor).

1CD-0-3

Carcinoma, squamous cell, NOS 8070/3

CRCF: Site: esophagus, proximal third c15.3

Path: esophagus, cervical c15.0

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

hw
11/8/12

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Resection of esophagus

Tumor site: Cervical esophagus

Tumor size: 5.5 x 5 x 1 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lamina propria or submucosa

Lymph nodes: 1/1 positive for metastasis (Intraabdominal 1/1)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file c4d55b9d-c5c0-4786-859e-08ccbd3e358d (TCGA-IG-A51D.03DC554E-1F63-4775-B33C-8941E7950D3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).